Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-5684, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-5684-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

DIAGNOSIS

(A) RIGHT LOWER POLE TUMOR, PARTIAL NEPHRECTOMY:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE), FUHRMAN'S
NUCLEAR GRADE 2.

TUMOR MEASURES 4.7 CM IN MAXIMUM DIMENSION.

TUMOR PRESENT IN A VASCULAR SPACE AT THE MARGIN OF RESECTION. (SEE
COMMENT)

(B) 11TH RIB:

Segment of rib for gross inspection only.

(C) PERINEPHRIC FAT:

Adipose tissue, no tumor present.

COMMENT

The tumor is present as a bulging nodule in a large caliber vascular space at the parenchymal margin of resection extending to the inked surface indicated by the surgeon. The immunohistochemical stain for CD31 (vascular marker) highlights the endothelial surface of the vascular structure. This histologic finding is not diagnostic of renal vein involvement. Additional sections prepared from the frozen section block (A1FS) demonstrate a minute amount of adipose tissue adjacent to the vascular structure consistent with renal sinus adipose tissue. The tumor does not invade this adipose tissue or the perinephric adipose tissue.

GROSS DESCRIPTION

(A) RIGHT LOWER POLE TUMOR, INK AT MARGIN - A partial nephrectomy specimen (7.7 x 5.3 x 4.2 cm) including a portion of kidney and surrounding adipose. At the margin of resection is a protruding area of orange-yellow tumor (0.7 x 0.5 x 0.4 cm) marked with blue surgical ink. This area is re-inked blue. The remaining resection margin is tan-gray.

A 4.7 x 4.3 x 3.6 cm orange-yellow, partially cystic and hemorrhagic tumor is present. Focally within the tumor are small areas of gray mucoid material. The tumor is encapsulated by a rim of tan fibrous tissue. The tumor bulges into the adjacent perinephric adipose without gross infiltration.

The surrounding uninvolved renal parenchyma is unremarkable.

Representative sections of tumor and normal are submitted for tumor bank. A portion of the tumor is sequestered for potential electron microscopy.

INK CODE: Blue - reinked surgical ink, yellow - surgical
parenchymal margin, and black - Gerota's fascia.

SECTION CODE: A1, frozen section of protruding tumor nodule; A2, additional close margin, frozen; A3, nodule protruding at margin (mirror image to A1); A4, tumor and nearest fascia; A5-A6, tumor and surrounding normal kidney; A7, gray mucoid area of tumor; A8, cystic area of tumor; A9-A10, representative sections of tumor. [REDACTED]

*FS/DX: CARCINOMA PRESENT AT INKED MARGIN OF RESECTION. NO
APPARENT CAPSULE AT SITE OF POSITIVE MARGIN. PT:SM/msm

(B) 11TH RIB, GROSS ONLY - An irregular fragment of rib (3.5 x 1.0 x
0.5 cm). The specimen is entirely submitted for gross only. [REDACTED]

(C) PERINEPHRIC FAT - An irregular fragment of adipose tissue (7.5 x

[page 2 of 2]
[REDACTED]

6.0 x 1.0 cm). The specimen is serially sectioned and grossly unremarkable. Representative sections in C1 and C2. [REDACTED]

CLINICAL HISTORY

Right renal mass.

[REDACTED]

SNOMED CODES

T-71000, M-83123

[REDACTED]

Source: NCI Genomic Data Commons file f8949f29-db47-42f7-b817-e52291863cf8 (TCGA-CJ-5684.36810CC1-1D6E-4A09-9AE1-62E71DC9215F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).